Somatic mutation profile of tumor specimen TARGET-30-PASVRU-01A (aliquot TARGET-30-PASVRU-01A-01D) from TARGET case TARGET-30-PASVRU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 1.7 years (631 days).
Specimen TARGET-30-PASVRU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21e37aec-24c2-4787-bcec-a8453553e978.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASVRU-10A (Blood Derived Normal), aliquot TARGET-30-PASVRU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c03d0b0e-73d6-47ba-8227-118e5650ed2f

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCKBR | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV58098648; called by muse, mutect2, varscan2
- COL5A2 | c.4106G>T p.G1369V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759631023, COSV66407090; called by mutect2, varscan2
- GALNT10 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760733045, COSV51720394; called by muse, mutect2, varscan2
- ITGA10 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV65196012, COSV65197823; called by muse, mutect2, varscan2
- PDE6C | c.1718C>G p.T573S | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65114698; called by muse, mutect2, varscan2
- RELN | c.2950C>A p.H984N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as COSV58985756; called by muse, mutect2, varscan2
- SDK1 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs145189416; called by muse, mutect2, varscan2
- SPAM1 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56141169; called by muse, mutect2
- KEAP1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KEAP1 | c.103T>A p.S35T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RHCG | c.480C>T p.T160= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1012315227, COSV51514371; called by muse, mutect2, varscan2
- TTC36 | c.234C>A p.I78= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV57096119; called by muse, mutect2, varscan2
- PDE4D | c.456-59412G>T | Intron (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
